Somatic mutation profile of tumor specimen 0DE7FK from CCDI case PBBMTH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 4.2 years (1,534 days).
Specimen 0DE7FK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6d1b5cd-0127-4bb9-815b-9544536432c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07994019-bfee-47ed-801b-ac63526f3597

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, Silent 3, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 17/185 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ARRDC2 | c.1122C>G p.F374L | Missense Mutation (SNP) | VAF 128/552 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV55845745; called by muse, mutect2, varscan2
- CYP2C19 | c.643-1G>C p.X215_splice | Splice Site (SNP) | VAF 145/152 reads (95%) | catalogued as COSV64909197; called by muse, mutect2, varscan2
- LCE1F | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.005); catalogued as rs765145222, COSV57668783, COSV57669150; called by muse, varscan2
- ADD3 | c.690A>G p.I230M | Missense Mutation (SNP) | VAF 222/252 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- C19orf12 | c.246G>T p.K82N (on ENST00000392278 / NM_001031726.3; = p.K71N on NM_031448.6) | Missense Mutation (SNP) | VAF 264/422 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CEP120 | c.2588A>C p.Q863P | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- DSG4 | c.35T>G p.L12W | Missense Mutation (SNP) | VAF 22/776 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- FGD5 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 40/1238 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- GOLGA6L2 | c.2203G>C p.G735R | Missense Mutation (SNP) | VAF 329/553 reads (59%) | SIFT deleterious, low confidence (0.04); called by muse, varscan2
- SCNN1B | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 130/541 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- IL24 | c.543C>T p.D181= | Silent (SNP) | VAF 23/280 reads (8%) | catalogued as rs377743802; called by muse, mutect2
- KIF5B | c.2010A>G p.E670= | Silent (SNP) | VAF 189/543 reads (35%) | called by muse, mutect2, varscan2
- TAF3 | c.531C>A p.G177= | Silent (SNP) | VAF 98/316 reads (31%) | called by muse, mutect2, varscan2
- HNRNPA2B1 | c.511+73_511+74del | Intron (DEL) | VAF 24/54 reads (44%) | called by mutect2, varscan2
- LDLRAP1 | c.748-22C>G | Intron (SNP) | VAF 37/430 reads (9%) | catalogued as rs1348478113; called by muse, mutect2
- MYEF2 | c.-30G>A | 5'UTR (SNP) | VAF 79/213 reads (37%) | called by muse, mutect2, varscan2
- SLC25A45 | c.154-57G>A | Intron (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.1855-479C>T | Intron (SNP) | VAF 46/668 reads (7%) | catalogued as rs1349047809; called by muse, mutect2
